Gene-level copy-number profile of tumor specimen ALCH-B1KV-TTP1-A from ALCHEMIST case ALCH-B1KV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.8 years (27,313 days).
Specimen ALCH-B1KV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 28c8985a-b73d-4089-8822-a3f28eeb68c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1KV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/88eb581d-8f43-41c5-b533-374bc5dfe43f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,947; copy number 2: 53,906; copy number 3: 2,357; copy number 4: 134; copy number 5: 10; copy number 6: 1; copy number 7: 1; copy number 9: 1; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,208,834–110,209,987, 1 gene: LINC02586.
- chr2:25,369,136–25,375,845, 1 gene: ARNILA.
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr5:139,848,290–139,856,389, 1 gene (within-gene range 0–1): AC008667.2.
- chr12:118,136,124–118,145,584, 1 gene: PEBP1.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr19:22,520,995–22,533,494, 2 genes (within-gene range 0–1): AC011467.1, LINC01233.
- chr20:64,080,082–64,101,162, 3 genes: OPRL1, LKAAEAR1, AL121581.3.
- chr22:41,244,779–41,286,187, 2 genes: RANGAP1, MIR6889.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,114,838–90,115,402, 1 gene, copy number 7 (within-gene range 1–7): IGKV3D-15.
- chr2:242,175,181–242,175,634, 1 gene, copy number 5: RPL23AP88.
- chr6:32,552,713–32,560,022, 1 gene, copy number 6 (within-gene range 3–6): HLA-DRB6.
- chr8:144,051,266–144,063,965, 2 genes, copy number 11 (within-gene range 4–11): OPLAH, MIR6846.
- chr9:136,721,366–136,758,543, 8 genes, copy number 5–9 (within-gene range 4–9): SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, LCN8.
- chr20:64,073,181–64,079,988, 2 genes, copy number 5: RGS19, MIR6813.

Autosomal genes at a single copy (total copy number 1): 1,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
